TCGA case TCGA-DQ-7595 — Head and Neck Squamous Cell Carcinoma (TCGA-HNSC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Larynx; Tissue source site: University Of Michigan. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/f6ebe511-a4df-4310-bd59-3a46d43f100b

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 53 years; Vital status: Alive.

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; ICD-10 code: C32.9; Tissue or organ of origin: Larynx, NOS; Site of resection or biopsy: Head, face or neck, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 53.5 years (19,530 days); Year of diagnosis: 2011; AJCC staging edition: 7th; AJCC clinical T: T2; AJCC clinical N: N0; AJCC clinical M: M0; AJCC clinical stage: Stage II; AJCC pathologic T: TX; AJCC pathologic N: NX; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin; Days to treatment start: 34 days; Days to treatment end: 62 days; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 34 days; Days to treatment end: 85 days; Treatment dose: 70 Gy; Treatment outcome: Complete Response; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Chemotherapy; Treatment intent type: Cure; Days to treatment end: 85 days; Treatment outcome: No Measurable Disease; Chemo concurrent to radiation: Yes.

Follow-up (3 entries)
- Days to follow up: 324 days; Disease response: Tumor Free.
- Days to follow up: 449 days (1.2 years); Disease response: Tumor Free.
- Days to follow up: 1,190 days (3.3 years); Disease response: Tumor Free.

Molecular and laboratory tests
- CDKN2A: Positive.

Exposures
- Alcohol history: Yes; Alcohol drinks per day: 10; Alcohol days per week: 4.
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 80; Tobacco smoking onset year: 1971.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-DQ-7595-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 0.3; Intermediate dimension: 0.2; Shortest dimension: 0.2.
  Slide TCGA-DQ-7595-01A-01-TS1: Section location: Top; Percent tumor cells: 50; Percent tumor nuclei: 60; Percent normal cells: 25; Percent necrosis: 0; Percent stromal cells: 25; Percent lymphocyte infiltration: 10.
- Sample TCGA-DQ-7595-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-DQ-7595-10D: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Head and Neck; Histologic diagnosis: Head & Neck Squamous Cell Carcinoma; Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free; Lymph nodes examined: No; Lymph node neck dissection indicator: No; Tobacco smoking history indicator: 2; Alcohol consumption frequency: 4.
- Follow-up form 1: New tumor event diagnosis indicator: No; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response; Treatment outcome at TCGA followup: Complete Remission/Response.
- Follow-up form 2: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response; Tumor status: Tumor free; Treatment outcome at TCGA followup: Complete Remission/Response; Tobacco smokeless use at diagnosis: No; Tobacco smokeless regular use: No; Definitive treatment method: Concurrent Chemotherapy; Definitive treatment evidence disease after: No; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,190 days; disease-specific survival: no event (censored), 1,190 days; disease-free interval: no event (censored), 1,190 days; progression-free interval: no event (censored), 1,190 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; sample TCGA-DQ-7595-01): tumor purity 0.59, ploidy 1.9, whole-genome doublings 0 (call status: maf_call).
